Somatic mutation profile of tumor specimen TCGA-QR-A70M-01A (aliquot TCGA-QR-A70M-01A-11D-A35D-08) from TCGA case TCGA-QR-A70M, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 38.6 years (14,091 days).
Specimen TCGA-QR-A70M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e567fb6-34b9-4a8d-b3a0-a592ffb9a761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70M-10A (Blood Derived Normal), aliquot TCGA-QR-A70M-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16df8351-68cc-4f83-9b91-76949477aef4

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 62/73 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCN4 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs758568832, COSV99137315; called by muse, mutect2, varscan2
- SLC13A4 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372605570; called by muse, mutect2, varscan2
- ABCA13 | c.5540T>G p.M1847R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZNF862 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- DDC | c.678G>A p.L226= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7132G>A | Intron (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- MIR654 | n.73T>C | RNA (SNP) | VAF 6/16 reads (38%) | catalogued as rs376452769; called by muse, varscan2
